Somatic mutation profile of tumor specimen TCGA-B8-A54F-01A (aliquot TCGA-B8-A54F-01A-11D-A25V-10) from TCGA case TCGA-B8-A54F, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 49.4 years (18,028 days).
Specimen TCGA-B8-A54F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f0e28e91-61cb-4834-8807-34e6b1f3d2a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B8-A54F-10A (Blood Derived Normal), aliquot TCGA-B8-A54F-10A-01D-A25V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/151817f4-a5fc-45c0-860f-c8aa8a0d5187

The open-access MAF lists 32 somatic variants for this specimen: 23 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 8, Frame Shift Del 4, Nonsense Mutation 2, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA6 | c.4595C>T p.P1532L | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52646067; called by muse, mutect2
- ACTRT3 | c.909C>A p.F303L | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as COSV100377503; called by muse, mutect2, varscan2
- ARHGAP12 | c.1702A>C p.K568Q | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.281); catalogued as COSV100260654; called by muse, varscan2
- ASH2L | c.188G>C p.G63A | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.066); catalogued as COSV99166994; called by muse, mutect2, varscan2
- ATP10B | c.931C>T p.R311W | Missense Mutation (SNP) | VAF 54/156 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs369273403, COSV58779704; called by muse, mutect2, varscan2
- CPEB4 | c.832C>G p.L278V | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.146); catalogued as COSV99437246; called by muse, mutect2
- DERL2 | c.344T>A p.V115E | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.616); catalogued as COSV99342377; called by muse, mutect2, varscan2
- IGSF8 | c.770_772del p.V257del | In Frame Del (DEL) | VAF 38/141 reads (27%) | catalogued as rs1288650520; called by pindel, varscan2
- INPPL1 | c.1999T>G p.S667A | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); catalogued as COSV99996327; called by muse, mutect2, varscan2
- IREB2 | c.1727A>G p.Y576C | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs1162974779, COSV99359518; called by muse, mutect2, varscan2
- MADD | c.2653G>T p.V885L | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.97); catalogued as COSV100211575; called by muse, mutect2, varscan2
- PLAAT2 | c.20G>T p.R7I | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as rs1207067324, COSV99738158; called by muse, mutect2, varscan2
- PLEKHF2 | c.713T>C p.M238T | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1415824040, COSV100193518; called by muse, mutect2, varscan2
- PRICKLE1 | c.531T>G p.I177M | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV100566288; called by muse, mutect2, varscan2
- RAP1GAP2 | c.1216C>T p.R406W | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs959378939, COSV54584092; called by muse, mutect2
- SLC5A12 | c.139C>T p.Q47* | Nonsense Mutation (SNP) | VAF 65/170 reads (38%) | catalogued as COSV99745083; called by muse, mutect2, varscan2
- VN1R4 | c.879C>A p.Y293* | Nonsense Mutation (SNP) | VAF 21/82 reads (26%) | catalogued as COSV100237449; called by muse, mutect2, varscan2
- XPOT | c.2522C>T p.A841V | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV100225605; called by muse, mutect2, varscan2
- ZNF79 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs764911536, COSV100688097; called by muse, varscan2
- HCFC2 | c.268del p.M90Wfs*24 | Frame Shift Del (DEL) | VAF 37/104 reads (36%) | called by mutect2, pindel, varscan2
- MTMR7 | c.1179_1186del p.K393Nfs*5 | Frame Shift Del (DEL) | VAF 5/32 reads (16%) | called by mutect2, pindel, varscan2
- PCLO | c.6350_6375del p.T2117Ifs*6 | Frame Shift Del (DEL) | VAF 9/68 reads (13%) | called by mutect2, pindel
- SLC44A3 | c.1952_1961del p.I651Rfs*15 (on ENST00000271227 / NM_001114106.3; = p.I603Rfs*15 on NM_152369.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 54/314 reads (17%) | called by mutect2, pindel
- CBLIF | c.426G>A p.L142= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as COSV99950989; called by muse, mutect2, varscan2
- GTPBP1 | c.1947A>G p.R649= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99323269; called by muse, mutect2
- MIS18BP1 | c.2805C>T p.V935= | Silent (SNP) | VAF 29/93 reads (31%) | catalogued as rs1350907596, COSV100173059; called by muse, mutect2, varscan2
- NPAS1 | c.1125G>A p.G375= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV99451415; called by muse, mutect2, varscan2
- RYR2 | c.7623C>T p.H2541= | Silent (SNP) | VAF 30/111 reads (27%) | catalogued as rs753435083, COSV100771088; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC9A6 | c.282C>A p.R94= | Silent (SNP) | VAF 8/121 reads (7%) | catalogued as COSV100857914; called by muse, mutect2
- TGM7 | c.72C>T p.H24= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as COSV101476873; called by muse, mutect2, varscan2
- USH2A | c.10119A>C p.G3373= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as COSV100237004; called by muse, mutect2, varscan2
- CACNA1D | c.1478+302G>A | Intron (SNP) | VAF 9/26 reads (35%) | catalogued as COSV99858615; called by muse, mutect2, varscan2
